Somatic mutation profile of tumor specimen TCGA-HU-A4HD-01A (aliquot TCGA-HU-A4HD-01A-11D-A25D-08) from TCGA case TCGA-HU-A4HD, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 73.1 years (26,699 days).
Specimen TCGA-HU-A4HD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 136c5d7c-1203-43fd-b87f-1de5d2c74168.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HU-A4HD-10A (Blood Derived Normal), aliquot TCGA-HU-A4HD-10A-01D-A25E-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d248f720-cf52-4583-bc5a-6d2a59445131

The open-access MAF lists 203 somatic variants for this specimen: 152 protein-altering or splice-affecting, 46 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 131, Silent 46, Nonsense Mutation 11, Frame Shift Ins 4, Intron 2, Splice Site 2, Frame Shift Del 1, Splice Region 1, In Frame Del 1, 3'UTR 1, 5'UTR 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.216dup p.V73Rfs*76 | Frame Shift Ins (INS) | VAF 93/226 reads (41%) | catalogued as rs730882018, COSV104369723; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- ADAD2 | c.98G>A p.R33Q | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.372); catalogued as rs531866972, COSV51895390; called by muse, mutect2
- AFF3 | c.1354dup p.H452Pfs*8 | Frame Shift Ins (INS) | VAF 7/18 reads (39%) | catalogued as rs759949420; called by mutect2, varscan2
- AKAP12 | c.5171C>G p.T1724S | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.03); catalogued as COSV53582412; called by muse, mutect2, varscan2
- AL592490.1 | c.2614A>T p.I872F | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.296); catalogued as COSV69427979; called by muse, mutect2, varscan2
- ALG5 | c.688G>C p.G230R | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.114); catalogued as COSV53507523; called by muse, mutect2, varscan2
- ANGPT1 | c.1038G>T p.M346I | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.035); catalogued as COSV52457633; called by muse, mutect2, varscan2
- AP2A1 | c.2589G>C p.K863N | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); catalogued as COSV58243063; called by muse, varscan2
- AP2A1 | c.2637G>A p.W879* | Nonsense Mutation (SNP) | VAF 6/24 reads (25%) | catalogued as COSV58243073; called by muse, varscan2
- APOH | c.540G>A p.M180I | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs1321630633, COSV52775091; called by muse, mutect2, varscan2
- ARHGAP6 | c.2135C>G p.S712* | Nonsense Mutation (SNP) | VAF 68/179 reads (38%) | catalogued as COSV57303799; called by muse, mutect2, varscan2
- ATG9A | c.2045C>G p.A682G | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV54701044; called by muse, mutect2, varscan2
- BACH2 | c.1319A>G p.Q440R | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.97); PolyPhen benign (0.005); catalogued as COSV57609583; called by muse, mutect2, varscan2
- BARD1 | c.2119C>T p.P707S | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1045454971, COSV53617677; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BBS9 | c.1279G>C p.A427P | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV54188216; called by muse, mutect2
- BCR | c.2561G>A p.R854H | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as rs372445084; called by muse, mutect2, varscan2
- C4BPA | c.276G>T p.Q92H | Missense Mutation (SNP) | VAF 44/87 reads (51%) | SIFT tolerated (0.79); PolyPhen benign (0.009); catalogued as COSV65537713; called by muse, mutect2, varscan2
- CADPS | c.3365C>A p.T1122N | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.039); catalogued as rs151301388; called by muse, mutect2, varscan2
- CALML5 | c.417C>A p.F139L | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs1307232470, COSV66702756; called by muse, mutect2, varscan2
- CDH23 | c.1213G>A p.V405I | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.95); PolyPhen benign (0.01); catalogued as rs370549448; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CILP | c.2252G>A p.R751Q | Missense Mutation (SNP) | VAF 38/153 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs139906949; called by muse, mutect2, varscan2
- CLDN25 | c.96G>T p.Q32H | Missense Mutation (SNP) | VAF 39/149 reads (26%) | SIFT tolerated (0.62); PolyPhen benign (0.06); catalogued as COSV71620495; called by muse, mutect2, varscan2
- CNBD1 | c.1162C>T p.Q388* | Nonsense Mutation (SNP) | VAF 16/71 reads (23%) | catalogued as COSV73075196; called by muse, mutect2, varscan2
- CNGB3 | c.303G>C p.Q101H | Missense Mutation (SNP) | VAF 20/333 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV60698788; called by muse, mutect2
- CNPY3 | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as COSV58976780; called by muse, mutect2
- COQ3 | c.39G>T p.W13C | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.19); catalogued as COSV54642076; called by muse, mutect2, varscan2
- CSMD3 | c.714A>C p.E238D | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.965); catalogued as COSV52209949, COSV52211199; called by muse, mutect2, varscan2
- CTNNA3 | c.1982A>C p.K661T | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.113); catalogued as COSV65520898; called by muse, mutect2, varscan2
- CXCL8 | c.19G>T p.V7L | Missense Mutation (SNP) | VAF 37/176 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV56641434; called by muse, mutect2, varscan2
- CYLC2 | c.353G>A p.G118D | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs780357420, COSV66337727, COSV66339704; called by muse, mutect2, varscan2
- CYP51A1 | c.289A>T p.K97* | Nonsense Mutation (SNP) | VAF 7/19 reads (37%) | catalogued as COSV50154390; called by muse, mutect2, varscan2
- DCDC1 | c.1652C>A p.S551Y | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); catalogued as COSV60857051, COSV60859084; called by muse, mutect2, varscan2
- DCHS1 | c.6016A>G p.T2006A | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV55043105; called by muse, mutect2, varscan2
- DDX60 | c.3398del p.L1133Yfs*4 | Frame Shift Del (DEL) | VAF 12/52 reads (23%) | catalogued as rs778036194; called by mutect2, varscan2
- DIAPH3 | c.3260-1G>T p.X1087_splice (on ENST00000400324 / NM_001042517.2; = p.X824_splice on NM_030932.3) | Splice Site (SNP) | VAF 10/44 reads (23%) | catalogued as COSV99932569; called by mutect2, varscan2
- DOCK2 | c.332A>G p.K111R | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.62); PolyPhen benign (0.023); catalogued as rs878984678, COSV56989223, COSV99911338; called by muse, mutect2, varscan2
- DOCK4 | c.2033T>C p.L678P | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV70243387; called by muse, mutect2, varscan2
- DST | c.6982C>T p.P2328S | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.001); catalogued as rs189168657, COSV99749555; called by muse, mutect2, varscan2
- DST | c.3913T>A p.W1305R (on ENST00000361203 / NM_001374722.1; = p.W979R on NM_001723.6) | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99749558; called by muse, mutect2, varscan2
- ELAPOR1 | c.1477G>T p.E493* | Nonsense Mutation (SNP) | VAF 39/131 reads (30%) | catalogued as COSV64041336; called by muse, mutect2, varscan2
- ELOA2 | c.1333G>A p.G445S | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.067); catalogued as rs766103603, COSV55304399; called by muse, mutect2, varscan2
- EPHA6 | c.2054A>C p.N685T (on ENST00000389672 / NM_001080448.3; = p.N77T on NM_173655.4) | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as COSV101060570; called by muse, mutect2, varscan2
- ETV6 | c.386T>C p.L129P | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.341); catalogued as rs1485094502, COSV67154441; called by muse, mutect2, varscan2
- EYA4 | c.340G>A p.D114N | Missense Mutation (SNP) | VAF 47/174 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV62061147; called by muse, mutect2, varscan2
- FAM209A | c.226C>G p.Q76E | Missense Mutation (SNP) | VAF 29/182 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as COSV54769198; called by muse, mutect2, varscan2
- FBLN2 | c.2842G>A p.E948K | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.052); catalogued as COSV55491307; called by muse, mutect2, varscan2
- FBXO16 | c.472C>G p.Q158E | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV60777768; called by muse, mutect2, varscan2
- FERMT1 | c.1790C>G p.T597S | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.012); catalogued as COSV54097558; called by muse, mutect2, varscan2
- FLG | c.5495C>T p.S1832L | Missense Mutation (SNP) | VAF 442/649 reads (68%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.461); catalogued as rs772920605, COSV64238908, COSV64242396; called by muse, mutect2, varscan2
- FN1 | c.3632C>A p.T1211N | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.731); catalogued as COSV60553735, COSV60564703; called by muse, mutect2, varscan2
- FOXN1 | c.1571A>G p.D524G | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV56884346; called by muse, mutect2, varscan2
- FRRS1L | c.446C>T p.S149F | Missense Mutation (SNP) | VAF 10/176 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV73746967; called by muse, mutect2
- GDPD5 | c.62G>T p.G21V | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV61130389; called by muse, mutect2, varscan2
- GLYATL1 | c.493G>A p.E165K (on ENST00000317391 / NM_001354699.1; = p.E196K on NM_080661.4) | Missense Mutation (SNP) | VAF 28/49 reads (57%) | SIFT tolerated (0.81); PolyPhen benign (0.165); catalogued as COSV55611249; called by mutect2, varscan2
- GPR20 | c.475C>T p.R159C | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.042); catalogued as rs765239165, COSV66685100; called by muse, mutect2, varscan2
- GRIK2 | c.2139G>T p.R713S | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as COSV59774192; called by muse, mutect2, varscan2
- H3-3A | c.143C>A p.A48E | Missense Mutation (SNP) | VAF 29/42 reads (69%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.737); catalogued as COSV64732350, COSV64734429; called by muse, mutect2, varscan2
- HMCN1 | c.13069T>G p.S4357A | Missense Mutation (SNP) | VAF 6/77 reads (8%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.963); catalogued as rs1558246037, COSV54943163; called by muse, mutect2
- HNRNPA2B1 | c.775A>T p.S259C (on ENST00000354667 / NM_031243.3; = p.S247C on NM_002137.4) | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.339); catalogued as COSV61161271; called by muse, mutect2, varscan2
- HTT | c.6188G>T p.R2063L | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); catalogued as COSV100750255; called by muse, mutect2, varscan2
- IARS1 | c.824T>C p.I275T | Missense Mutation (SNP) | VAF 29/150 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.2); catalogued as COSV65117189; called by muse, mutect2, varscan2
- IK | c.514C>T p.Q172* | Nonsense Mutation (SNP) | VAF 7/26 reads (27%) | catalogued as COSV70258259; called by muse, mutect2, varscan2
- INPP5D | c.3007A>G p.T1003A (on ENST00000445964 / NM_001017915.3; = p.T1002A on NM_005541.5) | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV64040550; called by muse, mutect2, varscan2
- KBTBD3 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.113); catalogued as COSV73241640; called by muse, mutect2, varscan2
- KMT2D | c.9295C>T p.R3099C | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs747415183, COSV56488003; called by muse, mutect2, varscan2
- KRT27 | c.467A>T p.N156I | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56971785, COSV56973443; called by muse, mutect2, varscan2
- LINGO2 | c.929G>A p.R310H | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.041); catalogued as rs559778213, COSV58059657; called by muse, mutect2, varscan2
- LRP2 | c.9821G>A p.S3274N | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.363); catalogued as rs780200412, COSV55575479; called by muse, mutect2, varscan2
- LRP5 | c.3835C>T p.R1279C | Missense Mutation (SNP) | VAF 42/197 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53713220; called by muse, mutect2, varscan2
- LRRC30 | c.103C>T p.L35F | Missense Mutation (SNP) | VAF 76/179 reads (42%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.942); catalogued as COSV67302352; called by muse, mutect2, varscan2
- MAP4K2 | c.1597C>G p.L533V | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.987); catalogued as COSV53648673; called by muse, mutect2, varscan2
- MARCHF4 | c.692C>T p.T231M | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.849); catalogued as rs751762461, COSV56102800; called by muse, mutect2, varscan2
- MDGA2 | c.2645C>A p.A882D (on ENST00000399232 / NM_001113498.2; = p.A584D on NM_182830.4) | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62115921; called by muse, mutect2, varscan2
- MED6 | c.170T>A p.L57* | Nonsense Mutation (SNP) | VAF 8/43 reads (19%) | catalogued as COSV56451179; called by muse, mutect2, varscan2
- MKLN1 | c.1300C>G p.Q434E | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.017); catalogued as rs1253609432, COSV61762904; called by muse, mutect2, varscan2
- MME | c.1541A>C p.N514T | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.946); catalogued as COSV64707387, COSV64710978; called by muse, mutect2, varscan2
- MNT | c.570G>T p.Q190H | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.549); catalogued as COSV99437883; called by muse, mutect2
- MRGPRX1 | c.823G>A p.V275M | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.907); catalogued as rs1463450834, COSV57109601; called by muse, mutect2, varscan2
- MUC16 | c.34939C>G p.P11647A | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.376); catalogued as COSV67495404; called by muse, mutect2, varscan2
- MUC5B | c.6137C>T p.A2046V | Missense Mutation (SNP) | VAF 45/250 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs1031020920, COSV71595684; called by muse, mutect2, varscan2
- MYO1F | c.1396G>A p.A466T | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as rs761238426, COSV57793909; called by muse, mutect2, varscan2
- MYOM2 | c.3892A>G p.K1298E | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50708181, COSV50777230; called by muse, mutect2, varscan2
- NAV2 | c.1763C>T p.P588L (on ENST00000396087 / NM_001244963.2; = p.P565L on NM_145117.5) | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62336098; called by muse, mutect2, varscan2
- NDST3 | c.1887A>C p.K629N | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.506); catalogued as COSV56630112; called by muse, mutect2, varscan2
- NDUFAF6 | c.469G>A p.D157N | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.41); catalogued as rs766120751, COSV54410941; called by muse, mutect2, varscan2
- NOS2 | c.2009G>A p.R670H | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as rs1308806887, COSV58227623; called by muse, mutect2, varscan2
- NPR2 | c.2927G>A p.R976H | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1309870543, COSV52413548; called by muse, mutect2, varscan2
- NPSR1 | c.946C>A p.Q316K | Missense Mutation (SNP) | VAF 39/173 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV62207943; called by muse, mutect2, varscan2
- NXPE3 | c.302C>T p.T101I | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV56292355, COSV99840260; called by muse, mutect2, varscan2
- OR5K1 | c.449T>A p.I150K | Missense Mutation (SNP) | VAF 28/144 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.073); catalogued as COSV60305367, COSV60305372; called by muse, mutect2, varscan2
- OR5K2 | c.764T>A p.I255N | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as rs996965524, COSV71143530; called by muse, mutect2, varscan2
- OR8J1 | c.218A>C p.N73T | Missense Mutation (SNP) | VAF 46/102 reads (45%) | SIFT tolerated (0.24); PolyPhen benign (0.031); catalogued as COSV57320153; called by muse, mutect2, varscan2
- PCDH15 | c.2923C>G p.P975A | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.83); PolyPhen benign (0.078); catalogued as COSV57280092, COSV57397676; called by muse, mutect2, varscan2
- PCDHGC3 | c.874C>T p.R292W | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV52768976; called by muse, mutect2, varscan2
- PDIA5 | c.52C>T p.P18S | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.022); catalogued as COSV60252674; called by muse, mutect2, varscan2
- PHYHIP | c.424C>T p.R142C | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58689470; called by muse, mutect2, varscan2
- PNLIPRP1 | c.615A>T p.E205D | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.417); catalogued as COSV62613584; called by muse, mutect2, varscan2
- PPP3R1 | c.157C>A p.P53T | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52249524; called by muse, mutect2, varscan2
- PRSS38 | c.754G>T p.E252* | Nonsense Mutation (SNP) | VAF 6/77 reads (8%) | catalogued as COSV100816294; called by muse, mutect2
- RAD51AP2 | c.1172A>T p.K391I | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.518); catalogued as COSV67589298; called by muse, mutect2, varscan2
- RDH10 | c.704G>C p.G235A | Missense Mutation (SNP) | VAF 13/131 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV53584492, COSV53584803; called by muse, mutect2
- RGS9BP | c.59A>C p.Y20S | Missense Mutation (SNP) | VAF 45/114 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV100042832, COSV60136164; called by muse, mutect2, varscan2
- RNF6 | c.755G>A p.R252H | Missense Mutation (SNP) | VAF 41/126 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs774282689, COSV60420615; called by muse, mutect2, varscan2
- ROBO2 | c.2117T>G p.V706G | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.233); catalogued as COSV59940251; called by muse, mutect2, varscan2
- RSF1 | c.7A>G p.T3A | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0); catalogued as rs777101364, COSV100406774; called by muse, varscan2
- RXFP2 | c.1650T>A p.F550L | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.042); catalogued as COSV53641209; called by muse, mutect2, varscan2
- SEMA5A | c.2379G>C p.W793C | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV66806096; called by muse, mutect2, varscan2
- SESTD1 | c.70C>T p.R24W | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1383284955, COSV70568577; called by muse, mutect2, varscan2
- SETX | c.6583C>G p.L2195V | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV56395070; called by muse, mutect2, varscan2
- SF3B4 | c.541G>A p.D181N | Missense Mutation (SNP) | VAF 78/119 reads (66%) | SIFT tolerated (0.08); PolyPhen benign (0.325); catalogued as COSV54965164, COSV54966987; called by muse, mutect2, varscan2
- SIGLEC11 | c.248G>T p.G83V | Missense Mutation (SNP) | VAF 10/125 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs1407440654, COSV70221949; called by muse, mutect2
- SLC26A11 | c.11C>T p.S4L | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV58338420; called by mutect2, varscan2
- SLC6A19 | c.523T>G p.F175V | Missense Mutation (SNP) | VAF 54/127 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV58674712; called by muse, mutect2, varscan2
- SLITRK1 | c.1426C>A p.L476I | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV65677402, COSV65677692; called by muse, mutect2, varscan2
- SMC4 | c.3809A>C p.N1270T | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59088540; called by muse, mutect2, varscan2
- SNRNP27 | c.53C>T p.S18F | Missense Mutation (SNP) | VAF 26/201 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.951); catalogued as COSV54912909; called by muse, mutect2, varscan2
- SORCS3 | c.1090G>T p.G364* | Nonsense Mutation (SNP) | VAF 6/35 reads (17%) | catalogued as COSV100864263, COSV63825823; called by muse, mutect2, varscan2
- SORCS3 | c.1466T>G p.I489S | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.179); catalogued as COSV63825707; called by muse, mutect2, varscan2
- SOS2 | c.3149G>A p.G1050D | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.758); catalogued as COSV53574828; called by muse, mutect2, varscan2
- SPEN | c.7723C>A p.P2575T | Missense Mutation (SNP) | VAF 33/178 reads (19%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); catalogued as COSV65367615; called by muse, mutect2, varscan2
- SPIB | c.409G>T p.D137Y | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.575); catalogued as COSV99569701; called by mutect2, varscan2
- STARD13 | c.234A>C p.L78F | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.424); catalogued as COSV55236974; called by muse, mutect2, varscan2
- SUPT6H | c.2597G>A p.R866H | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.793); catalogued as rs370622238; called by muse, mutect2, varscan2
- SYDE2 | c.1457C>T p.A486V | Missense Mutation (SNP) | VAF 39/63 reads (62%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV52318176; called by muse, mutect2, varscan2
- TAF1D | c.72T>A p.D24E | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV58682375; called by muse, mutect2, varscan2
- TBC1D16 | c.1228C>T p.Q410* | Nonsense Mutation (SNP) | VAF 15/44 reads (34%) | catalogued as rs1453541356, COSV60481482; called by muse, mutect2, varscan2
- TBRG4 | c.1742G>A p.R581H | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as rs182333366; called by muse, mutect2
- TELO2 | c.1129C>T p.R377W | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.528); catalogued as rs200293618; called by muse, mutect2, varscan2
- TGFBR2 | c.1081C>T p.L361F | Missense Mutation (SNP) | VAF 40/190 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55461000; called by muse, mutect2, varscan2
- TOX4 | c.1043C>T p.S348L | Missense Mutation (SNP) | VAF 34/162 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.227); catalogued as COSV52971422; called by muse, mutect2
- TRIOBP | c.4208C>T p.P1403L | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); catalogued as COSV60384647; called by muse, mutect2
- TTN | c.56506G>C p.E18836Q (on ENST00000591111; = p.E11412Q on NM_003319.4) | Missense Mutation (SNP) | VAF 16/55 reads (29%) | PolyPhen possibly damaging (0.711); catalogued as COSV60360730; called by muse, mutect2, varscan2
- VPS13D | c.2167G>T p.D723Y | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as COSV99165318; called by muse, mutect2, varscan2
- VSNL1 | c.340G>A p.G114S | Missense Mutation (SNP) | VAF 49/115 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV54603848; called by muse, mutect2, varscan2
- VWA8 | c.5296G>C p.D1766H | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV65000698; called by muse, mutect2
- WDR35 | c.416T>C p.V139A | Missense Mutation (SNP) | VAF 33/190 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV55607163; called by muse, varscan2
- WWP1 | c.1996A>G p.M666V | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1391523249, COSV55364413; called by muse, mutect2, varscan2
- ZC3H15 | c.100A>C p.K34Q | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV61923706; called by mutect2, varscan2
- ZCCHC2 | c.3536G>T p.*1179Lext*3 | Nonstop Mutation (SNP) | VAF 8/14 reads (57%) | catalogued as COSV54041280; called by muse, mutect2, varscan2
- ZFHX4 | c.9209C>A p.A3070D | Missense Mutation (SNP) | VAF 36/388 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.961); catalogued as COSV51494106; called by muse, mutect2
- ZIC2 | c.688G>A p.A230T | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.063); catalogued as COSV100891743; called by mutect2, varscan2
- ZMYM2 | c.2581A>G p.T861A | Missense Mutation (SNP) | VAF 43/190 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV67037781; called by muse, mutect2, varscan2
- ZNF229 | c.1545T>G p.H515Q | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.168); catalogued as COSV52165038; called by muse, mutect2, varscan2
- ZNF30 | c.748C>G p.H250D | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57855434; called by muse, mutect2
- ZNF569 | c.607A>T p.R203* | Nonsense Mutation (SNP) | VAF 8/88 reads (9%) | catalogued as COSV57598914, COSV57599325; called by muse, mutect2
- ZNF684 | c.1027C>T p.L343F | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.411); catalogued as COSV65519756; called by muse, mutect2, varscan2
- ADGRV1 | c.18019_18021del p.E6007del | In Frame Del (DEL) | VAF 8/14 reads (57%) | called by mutect2, varscan2
- AKAP13 | c.770_771dup p.E258Lfs*24 | Frame Shift Ins (INS) | VAF 19/76 reads (25%) | called by mutect2, pindel, varscan2
- CKMT2 | c.879+3_879+4dup | Splice Region (INS) | VAF 4/20 reads (20%) | called by mutect2, pindel, varscan2
- CPNE1 | c.715-28_722del p.X239_splice (on ENST00000352393; = p.X244_splice on NM_003915.5) | Splice Site (DEL) | VAF 21/151 reads (14%) | called by mutect2, pindel
- KYNU | c.1261dup p.R421Kfs*6 | Frame Shift Ins (INS) | VAF 8/29 reads (28%) | called by mutect2, pindel, varscan2
- PTPN20 | c.1192A>G p.T398A (on ENST00000374339 / NM_001042357.4; = p.N214S on NM_015605.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 74/277 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- ABT1 | c.786C>T p.S262= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as rs368187388, COSV51293254; called by muse, mutect2, varscan2
- ACSBG1 | c.1749C>T p.I583= | Silent (SNP) | VAF 23/63 reads (37%) | catalogued as rs556850320, COSV51910232, COSV51911155; called by muse, mutect2, varscan2
- ADH5 | c.672C>T p.I224= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV56447116; called by muse, mutect2, varscan2
- ANK1 | c.5178G>A p.T1726= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as rs756122138, COSV55880551; called by muse, mutect2, varscan2
- ARHGEF26 | c.430C>T p.L144= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as COSV62848482; called by mutect2, varscan2
- ASTN2 | c.1518C>T p.T506= (on ENST00000313400 / NM_001365069.1; = p.T455= on NM_014010.5) | Silent (SNP) | VAF 22/52 reads (42%) | catalogued as COSV57818621; called by muse, mutect2, varscan2
- C3orf14 | c.204A>G p.L68= | Silent (SNP) | VAF 11/94 reads (12%) | catalogued as COSV51707668; called by muse, mutect2, varscan2
- CA10 | c.195G>T p.R65= | Silent (SNP) | VAF 29/142 reads (20%) | catalogued as COSV53358460, COSV53373694; called by muse, mutect2, varscan2
- CNR1 | c.669C>A p.A223= | Silent (SNP) | VAF 37/57 reads (65%) | catalogued as COSV62991488; called by muse, mutect2, varscan2
- DIDO1 | c.5247G>A p.P1749= | Silent (SNP) | VAF 34/203 reads (17%) | catalogued as COSV56634263; called by muse, mutect2, varscan2
- EIF2A | c.1158A>C p.G386= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV56409024; called by muse, mutect2, varscan2
- ELFN2 | c.1866G>A p.A622= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as rs1238188762, COSV68745340, COSV68746598; called by muse, mutect2, varscan2
- GABRA3 | c.228C>T p.D76= | Silent (SNP) | VAF 15/31 reads (48%) | catalogued as rs201122592, COSV64798706; called by muse, mutect2, varscan2
- GABRA5 | c.813C>T p.T271= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as rs368673573, COSV100165545; called by muse, mutect2, varscan2
- GFAP | c.114C>T p.S38= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as COSV53653453; called by muse, mutect2, varscan2
- GNAS | c.93G>A p.Q31= | Silent (SNP) | VAF 8/65 reads (12%) | catalogued as rs780295677, CD103548, COSV99668758; called by muse, mutect2, varscan2
- GPR3 | c.540C>T p.G180= | Silent (SNP) | VAF 8/122 reads (7%) | catalogued as COSV64995080; called by muse, mutect2
- HMCN1 | c.8220C>T p.T2740= | Silent (SNP) | VAF 30/54 reads (56%) | catalogued as rs562987367, COSV54886135; called by muse, mutect2, varscan2
- ITSN1 | c.1851A>G p.Q617= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as rs1310784835, COSV66086231; called by muse, mutect2, varscan2
- KCTD19 | c.1320G>C p.G440= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV58575334; called by mutect2, varscan2
- MAGEH1 | c.120A>G p.V40= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as COSV61679264, COSV61679328; called by muse, mutect2, varscan2
- MAP2 | c.681G>C p.G227= | Silent (SNP) | VAF 29/91 reads (32%) | catalogued as COSV52308770; called by muse, mutect2, varscan2
- MPP3 | c.294G>A p.P98= | Silent (SNP) | VAF 9/55 reads (16%) | catalogued as rs1312010521, COSV68199318; called by muse, mutect2, varscan2
- MSX2 | c.501C>T p.L167= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as COSV53328325; called by muse, mutect2, varscan2
- NUDC | c.867G>A p.K289= | Silent (SNP) | VAF 39/125 reads (31%) | catalogued as COSV57672173; called by muse, mutect2, varscan2
- OGDH | c.1323C>T p.V441= | Silent (SNP) | VAF 42/141 reads (30%) | catalogued as rs140074828; ClinVar: likely benign; called by muse, mutect2, varscan2
- OR1F1 | c.648T>G p.A216= | Silent (SNP) | VAF 22/94 reads (23%) | catalogued as COSV58962518; called by muse, mutect2, varscan2
- PCDHB4 | c.117G>A p.E39= | Silent (SNP) | VAF 19/67 reads (28%) | catalogued as COSV52027201; called by muse, mutect2, varscan2
- PCMTD2 | c.1005G>A p.V335= | Silent (SNP) | VAF 34/204 reads (17%) | catalogued as COSV55062834; called by muse, mutect2, varscan2
- PDE8B | c.1407C>A p.V469= | Silent (SNP) | VAF 18/90 reads (20%) | catalogued as COSV53746025; called by muse, mutect2, varscan2
- PLCB2 | c.345C>T p.F115= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as COSV99541352; called by muse, mutect2, varscan2
- PUS10 | c.63T>C p.C21= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV57455054; called by muse, mutect2
- PYGO1 | c.57T>C p.D19= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as COSV57350355; called by muse, mutect2, varscan2
- RBMXL2 | c.702G>A p.S234= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as rs1190794791, COSV60978927; called by muse, mutect2, varscan2
- RGS20 | c.372G>A p.P124= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as rs1169187546, COSV52022519; called by muse, mutect2
- ROPN1 | c.213G>A p.L71= | Silent (SNP) | VAF 16/71 reads (23%) | catalogued as rs752943751, COSV51741174; called by muse, mutect2, varscan2
- SCG2 | c.1722G>A p.P574= | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as rs186034917; called by muse, mutect2, varscan2
- SETD1A | c.207C>T p.S69= | Silent (SNP) | VAF 33/149 reads (22%) | catalogued as rs1244581833, COSV52692739; called by muse, mutect2, varscan2
- SHANK3 | c.3408T>C p.F1136= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV53191428; called by muse, mutect2, varscan2
- SLC35G5 | c.411T>C p.S137= | Silent (SNP) | VAF 60/208 reads (29%) | catalogued as COSV55315379; called by muse, varscan2
- TENM3 | c.2196C>T p.G732= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV69319862; called by muse, mutect2
- TRRAP | c.11475C>T p.L3825= (on ENST00000359863 / NM_001244580.1; = p.L3796= on NM_003496.3) | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as rs762119583, COSV62816127; called by muse, mutect2, varscan2
- TYRO3 | c.1848C>T p.L616= | Silent (SNP) | VAF 17/63 reads (27%) | catalogued as rs377341711; called by muse, mutect2, varscan2
- WIPI2 | c.522G>A p.A174= | Silent (SNP) | VAF 12/71 reads (17%) | catalogued as rs149226373; called by muse, mutect2, varscan2
- WWP1 | c.2340T>C p.F780= | Silent (SNP) | VAF 9/103 reads (9%) | catalogued as COSV55364421; called by muse, mutect2
- ZNF829 | c.153C>T p.C51= | Silent (SNP) | VAF 15/132 reads (11%) | catalogued as COSV66986991; called by muse, mutect2, varscan2
- AL353804.4 | chrX:73825336 A>T | 5'Flank (SNP) | VAF 7/34 reads (21%) | called by muse, mutect2
- MFSD4B | c.*608T>A | 3'UTR (SNP) | VAF 26/107 reads (24%) | catalogued as COSV64349500; called by muse, mutect2, varscan2
- PXN | c.831+2156G>A | Intron (SNP) | VAF 8/32 reads (25%) | called by muse, mutect2
- TMED10 | c.-2C>A | 5'UTR (SNP) | VAF 16/46 reads (35%) | catalogued as COSV100339517; called by muse, mutect2, varscan2
- TTN | c.10360+2919A>C | Intron (SNP) | VAF 14/62 reads (23%) | catalogued as COSV60360756; called by muse, mutect2, varscan2
